TARGET case TARGET-30-PAPBFP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/31670692-8782-5f5a-8ac4-5658c8e39df1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 4.9 years (1,800 days); Year of diagnosis: 2005; Days to last follow up: 586 days (1.6 years); INSS stage: Stage 4.

Biospecimens (2 samples)
- Sample TARGET-30-PAPBFP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPBFP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
